Surgical pathology report (de-identified scan), TCGA case TCGA-FW-A3R5, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site International Genomics Consortium, specimen TCGA-FW-A3R5-06A (Metastatic).

[page 1 of 2]
Surg Path Final Report

* Final Report *

* Final Report *

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

Collected:
Accession:
Physician:

PROCEDURE

Left parotidectomy with left functional neck dissection.

SPECIMEN:

Left parotid. No formalin-Fresh.

HISTORY

Carcinoma left parotid.

GROSS

Received fresh in a container labeled "left parotid" are two fragments of lobulated tan tissue (5.5 x 2.8 x 1.6 and 3.5 x 2 x 0.8 cm). The larger fragment is serially sectioned and has a 0.7 cm in greatest dimension discrete, firm, brown and tan nodule within 1 mm of the inked margin. A representative portion of the nodule is submitted for the project. A second discrete tan nodule (0.5 cm in diameter) is 0.4 cm from the nearest margin. The remaining tissue has a lobulated firm cut surface. The margins are marked with black ink. The smaller tissue fragment has a fatty cut surface with a palpable nodules suggestive of fatty lymph nodes (0.3 and 0.8 cm).

1. Large peripheral nodule. 2NS
- 2-3. Small eccentric nodule. 2NS
- 4-6. Representative sections of parotid parenchyma. 3SS
7. Bisected fatty tissue with possible small lymph node. 2NS
- 8-9. Bisected fatty tissue representing possible large lymph node. 2NS

MICROSCOPIC

See diagnosis.

DIAGNOSIS

Left parotid, left parotidectomy with left functional neck dissection:

Metastatic malignant melanoma involving two (of eight) intraparotid lymph nodes (2/8) (see comment).
Three benign periparotid lymph nodes (0/3).

CPT

Printed by:
Printed on:

ICD-O-3

melanoma, malignant
8720/3

Site = lymph node, parotid
3/5/12 RD C77.0

Page 1 of 2
(Continued)

[page 2 of 2]
Surg Path Final Report

* Final Report *

COMMENT

Two intraparotid lymph nodes are involved by metastatic malignant melanoma. The largest tumor focus is 7 mm (measured grossly) and one of the two lymph nodes appears entirely replaced by neoplasm with extracapsular extension. The neoplasm is composed of markedly enlarged, irregular cells with irregular nuclei, very prominent, red nucleoli, intranuclear inclusions and many bizarre-appearing cells. The cells show abundant eosinophilic cytoplasm and numerous mitotic figures are noted. They are disposed in nests and sheets. Some focal pigment is noted within the tumor cells. Immunohistochemical studies were performed to better characterize the neoplastic cells. They are strongly positive for an S-100 immunohistochemical stain, but negative for cytokeratin E1/E3 and CK8/18, as well as Melan A and HMB45 immunohistochemical stains. The intracellular pigment stains for a special stain consistent with melanin pigment. An iron special stain is negative within the intracellular pigment. The morphologic features and results of the immunohistochemical studies and special studies are most consistent with a diagnosis of metastatic malignant melanoma. This case was reviewed with Drs. and

(Electronic Signature)

Completed Action List:

* Order by : on

Type: Surg Path Final Report
Date:
Status:
Title: SURG PATH FINAL REPORT
Encounter info:

Printed by:
Printed on:

Page 2 of 2
(End of Report)

Source: NCI Genomic Data Commons file 189f94ca-88aa-4890-a2d5-4e61b79794bc (TCGA-FW-A3R5.D424CB2C-47D2-4182-85F8-9605C5613C1E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).